Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A4F0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A4F0-06A (Metastatic).

Patient: Xxxx

Translation of pathology report

Sample

ICD-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous, NOS C49.9
(pTSS) *hw*
10/1/12

Gross Pathology

Cryofixed specimen with a weight of 93 mg.

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 80 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

There is a high nucleo/cytoplasmatic ratio. The mitotic count is 1 mitosis per square millimetre. The tumor cells have a middle sized pigmented cytoplasm.

The tumor shows a nodular growth pattern.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

Source: NCI Genomic Data Commons file 9e1178f7-c874-42a2-a5ec-b339261e6920 (TCGA-FS-A4F0.F41C37C8-62FD-42F3-B376-9D8E291836E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).